CCDI case PBCHPC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8712fc68-17ea-4767-9173-4850ceff9c55

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Astroblastoma: ICD-O-3 morphology code: 9430/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 3.0 years (1,089 days).

Biospecimens (2 samples)
- Sample 0DS4M9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DS4MN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
